Somatic mutation profile of tumor specimen TCGA-DS-A0VN-01A (aliquot TCGA-DS-A0VN-01A-21D-A10S-08) from TCGA case TCGA-DS-A0VN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; Tumor grade: G2; Age at diagnosis: 47.7 years (17,433 days).
Specimen TCGA-DS-A0VN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 623f6d4e-ae46-41ed-aa76-09622d7d356d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DS-A0VN-10A (Blood Derived Normal), aliquot TCGA-DS-A0VN-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4b0d8e1-5cb6-4fb3-b8a1-36c4bd1b3d16

The open-access MAF lists 149 somatic variants for this specimen: 107 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 36, Nonsense Mutation 7, Intron 4, Splice Region 2, Frame Shift Ins 1, Frame Shift Del 1, Translation Start Site 1, 3'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.459C>A p.F153L | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.019); catalogued as COSV53994864; called by muse, mutect2, varscan2
- ACAP1 | c.2005C>G p.R669G | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.297); catalogued as COSV50143899; called by muse, mutect2, varscan2
- ADAD1 | c.66G>C p.K22N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56647958; called by muse, mutect2, varscan2
- ANK2 | c.4270C>T p.P1424S | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769015777, COSV52193536; called by muse, mutect2, varscan2
- AP002748.5 | c.1646G>A p.R549H | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.871); catalogued as rs202205304, CM117337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP2A1 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV62819621, COSV62819991; called by muse, mutect2, varscan2
- AP3B1 | c.338C>A p.A113E | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV54894889; called by muse, mutect2, varscan2
- ARHGAP6 | c.1667C>A p.T556N | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57304770; called by muse, mutect2, varscan2
- BEND2 | c.2302G>C p.A768P | Missense Mutation (SNP) | VAF 16/389 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV66221995; called by muse, mutect2
- BRWD1 | c.3727G>A p.E1243K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.138); catalogued as COSV100314278, COSV60904026; called by muse, mutect2
- CBX4 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV53964476, COSV53965467; called by muse, mutect2, varscan2
- CDCA2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs149260399, COSV55341688; called by muse, mutect2, varscan2
- CENPE | c.7497G>C p.L2499F | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54392460; called by muse, mutect2, varscan2
- CKAP2L | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100198825, COSV56698478; called by muse, mutect2, varscan2
- CLASRP | c.1752G>C p.K584N | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV55519951; called by muse, mutect2, varscan2
- CNTN3 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV55174482, COSV55187245; called by muse, mutect2, varscan2
- COG2 | c.559A>G p.S187G | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV64188696; called by muse, mutect2, varscan2
- CRB1 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66334677; called by muse, mutect2, varscan2
- CUL4A | c.2017C>G p.Q673E (on ENST00000375440 / NM_001008895.4; = p.Q573E on NM_003589.3) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV58376717; called by muse, mutect2, varscan2
- DMXL2 | c.7838G>A p.R2613Q | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1329282247, COSV51841045; called by muse, mutect2, varscan2
- DNAH3 | c.10099G>C p.E3367Q | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54533775; called by muse, mutect2, varscan2
- DNAJB1 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV54318413; called by muse, varscan2
- DNAJB1 | c.212-1G>A p.X71_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | catalogued as COSV54318422; called by muse, mutect2
- DPEP2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs564605320, COSV52053952; called by muse, mutect2, varscan2
- DYNC1H1 | c.7229C>T p.S2410F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV64143949; called by muse, mutect2, varscan2
- ECT2L | c.2100G>A p.L700= | Splice Region (SNP) | VAF 26/101 reads (26%) | catalogued as rs746561633, COSV62887629; called by muse, mutect2, varscan2
- EPHA10 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.058); catalogued as rs771803475, COSV60402406; called by muse, mutect2, varscan2
- EPHA2 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs764494279, COSV100626337, COSV64455026; called by muse, mutect2, varscan2
- ERV3-1 | c.986C>G p.S329* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV51426913, COSV51430277; called by muse, mutect2, varscan2
- FAM181A | c.978G>C p.Q326H | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV50892383; called by muse, mutect2, varscan2
- FBXO25 | c.469C>G p.Q157E (on ENST00000382824 / NM_183421.2; = p.Q90E on NM_012173.3) | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.117); catalogued as COSV52339465; called by muse, mutect2, varscan2
- FBXW7 | c.1557T>A p.Y519* (on ENST00000281708 / NM_001349798.2; = p.Y439* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 73/197 reads (37%) | catalogued as COSV55926259, COSV55929496; called by muse, mutect2, varscan2
- FER1L5 | c.5873C>T p.S1958L (on ENST00000623019; = p.S1922L on NM_001293083.2) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53844482; called by muse, mutect2, varscan2
- FHDC1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV52604030; called by muse, mutect2, varscan2
- FRMD5 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs765767175, COSV68724680; called by muse, mutect2, varscan2
- FRYL | c.6444G>A p.M2148I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1380027874, COSV51964628; called by muse, mutect2, varscan2
- GLRA4 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65457177; called by muse, mutect2, varscan2
- GPR183 | c.216T>G p.N72K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1347864373, COSV63122272; called by muse, mutect2, varscan2
- HAX1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55166925; called by muse, mutect2, varscan2
- HGD | c.697T>C p.W233R | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.301); catalogued as COSV52202102; called by muse, mutect2, varscan2
- HNRNPUL2 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as COSV53666885; called by muse, mutect2, varscan2
- IGFL4 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV66619104; called by muse, mutect2, varscan2
- IL12B | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as COSV51456284; called by muse, mutect2
- IQCB1 | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV60439936; called by muse, mutect2, varscan2
- IQCG | c.1283C>G p.S428* | Nonsense Mutation (SNP) | VAF 36/260 reads (14%) | catalogued as COSV54566957; called by muse, mutect2, varscan2
- KDM4A | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV64961051; called by muse, mutect2
- LCMT1 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66727705; called by muse, mutect2, varscan2
- LCN10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.55); catalogued as COSV57911879; called by muse, mutect2, varscan2
- MAEL | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV63306643; called by muse, mutect2, varscan2
- MED9 | c.124C>G p.Q42E | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.015); catalogued as COSV51958634; called by muse, mutect2, varscan2
- MESD | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); catalogued as COSV55726691; called by muse, mutect2, varscan2
- MMEL1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs904482620, COSV56527121; called by muse, mutect2, varscan2
- MOGAT1 | c.233G>T p.W78L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV71480167; called by muse, mutect2, varscan2
- MPEG1 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs574261219, COSV57090694; called by muse, mutect2, varscan2
- MYO18A | c.3497G>C p.G1166A | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62874894; called by muse, mutect2, varscan2
- NCK1 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56638811, COSV56640297; called by muse, mutect2, varscan2
- NF1 | c.1198C>T p.Q400* | Nonsense Mutation (SNP) | VAF 55/145 reads (38%) | catalogued as CM1311454, COSV62224610; called by muse, mutect2, varscan2
- NOX3 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV50167206; called by muse, varscan2
- NRIP1 | c.3284C>T p.S1095F | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV59660948; called by muse, mutect2, varscan2
- NRIP1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV59659708, COSV59660955; called by muse, mutect2, varscan2
- NUFIP1 | c.1257G>C p.K419N | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV64792436; called by muse, mutect2, varscan2
- OSBPL2 | c.841C>G p.H281D (on ENST00000313733 / NM_144498.4; = p.H269D on NM_014835.4) | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58220505; called by muse, mutect2, varscan2
- PAG1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV55062769; called by muse, mutect2, varscan2
- PCDHAC1 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53874108; called by muse, mutect2, varscan2
- PCSK4 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1055498140, COSV56301744; called by muse, mutect2, varscan2
- PDGFRB | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.89); catalogued as COSV55808518, COSV55810891; called by muse, mutect2, varscan2
- PHLDB1 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.683); catalogued as COSV61882395; called by muse, mutect2, varscan2
- PLEC | c.11563G>A p.E3855K (on ENST00000322810 / NM_201380.4; = p.E3745K on NM_000445.5) | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.494); catalogued as rs201007788, COSV59641689, COSV59705192; ClinVar: uncertain significance; called by muse, mutect2
- PLXNB2 | c.3805G>A p.E1269K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as COSV63781682; called by muse, mutect2, varscan2
- PON3 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1230081326, COSV55702469; called by muse, mutect2, varscan2
- PSME3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.965); catalogued as rs751193290, COSV53198717; called by muse, mutect2, varscan2
- PZP | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.05); catalogued as COSV54361805, COSV54372103; called by muse, mutect2, varscan2
- RALGPS2 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.09); catalogued as COSV61340398; called by muse, mutect2, varscan2
- RANGAP1 | c.1071C>T p.L357= | Splice Region (SNP) | VAF 17/67 reads (25%) | catalogued as COSV62365018; called by muse, varscan2
- RASA2 | c.765C>G p.I255M | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV53947391, COSV99656376; called by muse, mutect2
- RRP1B | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 54/147 reads (37%) | catalogued as rs1175860221, COSV61480814; called by muse, mutect2, varscan2
- SDCBP | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs769061064, COSV50703709; called by muse, mutect2, varscan2
- SEMA3A | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54891977; called by muse, mutect2, varscan2
- SETDB2 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV51647377; called by muse, mutect2, varscan2
- SGCD | c.179A>C p.N60T (on ENST00000435422 / NM_001128209.2; = p.N61T on NM_000337.5) | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.58); catalogued as COSV61918337; called by muse, varscan2
- SHROOM2 | c.3400C>A p.R1134S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as COSV66611272; called by muse, mutect2, varscan2
- SMG1 | c.9148G>A p.E3050K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV101244877, COSV67175222; called by muse, mutect2, varscan2
- SPEN | c.3490G>A p.D1164N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV65368313; called by muse, mutect2, varscan2
- SPHK1 | c.703G>C p.D235H (on ENST00000392496 / NM_001355139.2; = p.D249H on NM_021972.4) | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); catalogued as rs1392434887, COSV60065229, COSV60068412; called by muse, mutect2, varscan2
- SPTAN1 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs1277192295, COSV63990174; called by muse, mutect2, varscan2
- STX16 | c.460G>C p.E154Q (on ENST00000371141 / NM_001001433.3; = p.E133Q on NM_003763.6) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV100397673, COSV56608776; called by muse, mutect2, varscan2
- SYNPO | c.1067C>G p.S356C (on ENST00000394243 / NM_001166208.2; = p.S112C on NM_007286.6) | Missense Mutation (SNP) | VAF 93/297 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV56943902; called by muse, mutect2, varscan2
- TFCP2L1 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV55295819; called by muse, mutect2, varscan2
- TGM5 | c.1695C>G p.I565M (on ENST00000220420 / NM_201631.4; = p.I483M on NM_004245.4) | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs1352645143, COSV55012759; called by muse, mutect2, varscan2
- TIGIT | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs142063959; called by muse, mutect2, varscan2
- U2AF2 | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58276719; called by muse, mutect2, varscan2
- UBE2H | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as rs1563016621, COSV62922063; called by muse, mutect2, varscan2
- UBR3 | c.5158G>A p.E1720K | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV55844944, COSV55851580; called by muse, mutect2, varscan2
- URM1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV65717474; called by muse, mutect2, varscan2
- USP38 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1403235506, COSV61027738; called by muse, mutect2, varscan2
- VNN3 | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1340408420; called by muse, mutect2, varscan2
- ZC3H14 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV51769918, COSV51774439, COSV99193345; called by muse, mutect2, varscan2
- ZNF14 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV59851608, COSV59851878; called by muse, mutect2, varscan2
- ZNF14 | c.60G>C p.L20F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59851886; called by muse, varscan2
- ZNF518B | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV58722855, COSV58725024; called by muse, mutect2, varscan2
- ZNF540 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV57111911; called by muse, mutect2, varscan2
- ZNF74 | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.419); catalogued as rs745500441, COSV62622880; called by muse, mutect2, varscan2
- DDX52 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MTCL1 | c.2485G>C p.E829Q (on ENST00000306329 / NM_001378206.1; = p.E469Q on NM_015210.4) | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- PPIP5K2 | c.3420_3438del p.L1140Ffs*29 (on ENST00000358359 / NM_001276277.3; = p.L1119Ffs*29 on NM_015216.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 37/131 reads (28%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.6064dup p.R2022Kfs*8 | Frame Shift Ins (INS) | VAF 21/81 reads (26%) | called by mutect2, pindel, varscan2
- ADCY10 | c.942C>T p.I314= | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV63240202; called by muse, mutect2, varscan2
- AGBL5 | c.231C>T p.F77= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as COSV59938733; called by muse, mutect2
- AHNAK2 | c.4773C>T p.L1591= | Silent (SNP) | VAF 65/469 reads (14%) | catalogued as COSV60933683; called by muse, mutect2, varscan2
- ARHGEF2 | c.1179G>A p.K393= (on ENST00000361247 / NM_001162383.2; = p.K365= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as COSV58118160; called by muse, mutect2, varscan2
- CARD11 | c.1548G>A p.L516= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV62757348; called by muse, mutect2, varscan2
- CATSPER2 | c.852G>A p.P284= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs757123908, COSV58661261, COSV58662100; called by muse, mutect2, varscan2
- CCM2L | c.1059C>T p.L353= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs746910280; called by muse, mutect2, varscan2
- CCS | c.225C>G p.L75= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as COSV59581116; called by muse, mutect2, varscan2
- CEP78 | c.418C>T p.L140= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV52851032; called by muse, mutect2, varscan2
- CLCN6 | c.2586G>A p.L862= | Silent (SNP) | VAF 91/220 reads (41%) | catalogued as COSV56743673; called by muse, mutect2, varscan2
- COQ8A | c.216C>T p.F72= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as rs372825175; called by muse, mutect2, varscan2
- DCAF12L1 | c.837G>T p.A279= | Silent (SNP) | VAF 62/131 reads (47%) | catalogued as COSV64421649, COSV64422961; called by muse, mutect2, varscan2
- DIP2A | c.831G>C p.L277= | Silent (SNP) | VAF 64/216 reads (30%) | catalogued as COSV59488712; called by muse, mutect2, varscan2
- FGF21 | c.240C>G p.L80= | Silent (SNP) | VAF 90/223 reads (40%) | catalogued as COSV55811422; called by muse, mutect2, varscan2
- GADD45B | c.207C>T p.I69= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV53126887, COSV99298166; called by muse, mutect2, varscan2
- HELZ2 | c.4629C>T p.S1543= (on ENST00000467148 / NM_001037335.2; = p.S974= on NM_033405.3) | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs547243901, COSV71295485; called by muse, mutect2, varscan2
- IGKV1-5 | c.18C>T p.P6= | Silent (SNP) | VAF 88/269 reads (33%) | catalogued as rs757539286; called by muse, mutect2, varscan2
- LARP1 | c.135G>A p.P45= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs1041297330, COSV60432162; called by muse, mutect2, varscan2
- NFAT5 | c.3972C>G p.P1324= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as COSV100590512, COSV63033726; called by muse, mutect2, varscan2
- NLRP2 | c.2278C>T p.L760= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV54761465; called by muse, mutect2, varscan2
- RASA3 | c.1347G>C p.P449= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as rs546150726, COSV61874681; called by muse, mutect2, varscan2
- RNASE13 | c.402C>G p.L134= | Silent (SNP) | VAF 54/315 reads (17%) | catalogued as COSV58795769; called by muse, mutect2, varscan2
- RTL5 | c.1032C>T p.Y344= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as COSV65455311; called by muse, mutect2, varscan2
- SEC14L3 | c.156G>A p.S52= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs544591201, COSV53180759; called by muse, mutect2, varscan2
- SERINC2 | c.51C>T p.L17= (on ENST00000373709 / NM_178865.5; = p.L21= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/116 reads (11%) | catalogued as COSV65491985; called by muse, mutect2, varscan2
- SETD3 | c.1482G>A p.E494= | Silent (SNP) | VAF 46/282 reads (16%) | catalogued as COSV59287676; called by muse, mutect2, varscan2
- SFXN4 | c.384G>A p.L128= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV57461312; called by muse, mutect2, varscan2
- SRP68 | c.1368C>T p.L456= | Silent (SNP) | VAF 29/154 reads (19%) | catalogued as rs1396000785, COSV57165175; called by muse, mutect2, varscan2
- TMEM100 | c.24G>A p.E8= | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as COSV70117955, COSV70118364; called by muse, mutect2, varscan2
- TSC22D2 | c.801G>A p.Q267= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV62623818; called by muse, mutect2, varscan2
- UQCRC2 | c.1287G>A p.K429= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as COSV51672763, COSV51674508; called by muse, mutect2, varscan2
- USHBP1 | c.93C>T p.V31= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1043635275, COSV53105268; called by muse, mutect2, varscan2
- YY1 | c.381C>T p.F127= | Silent (SNP) | VAF 35/192 reads (18%) | catalogued as rs1346667862, COSV51764846; called by muse, mutect2, varscan2
- ZC3H8 | c.285A>G p.Q95= | Silent (SNP) | VAF 35/185 reads (19%) | catalogued as rs769632919, COSV55621342; called by muse, mutect2, varscan2
- ZFP37 | c.558G>A p.Q186= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as COSV65289040; called by muse, mutect2, varscan2
- ZNF184 | c.861C>T p.F287= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as COSV53005659; called by muse, mutect2, varscan2
- AP2A2 | c.*564G>A | 3'UTR (SNP) | VAF 29/72 reads (40%) | catalogued as COSV100172835; called by muse, mutect2, varscan2
- BMP1 | c.2107+1896G>C | Intron (SNP) | VAF 21/111 reads (19%) | called by muse, mutect2, varscan2
- CCDC144B | n.187G>A | RNA (SNP) | VAF 4/26 reads (15%) | catalogued as rs1472297509; called by muse, mutect2
- CIRBP | c.-7+722C>T | Intron (SNP) | VAF 4/26 reads (15%) | catalogued as rs763846849; called by mutect2, varscan2
- EDA | c.502+12C>T | Intron (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- PDE4B | c.634+626G>C | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100301906; called by muse, mutect2, varscan2
